CCDI case PBBWNX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a33bd0b2-7e5a-43d9-9984-43b0ec3b7e68

Demographics
Sex at birth: male; Race: american indian or alaska native; Vital status: Alive.

Diagnoses (1)
1. Craniopharyngioma, adamantinomatous: ICD-O-3 morphology code: 9351/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.2 years (1,547 days).

Biospecimens (3 samples)
- Sample 0DJIKP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJIL0: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJILE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
